TCGA case TCGA-DX-A23Y — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/319243bf-d96f-454f-b007-3468d76869df

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Dead; Days to death: 191 days.

Diagnoses (2)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 80.1 years (29,272 days); Year of diagnosis: 2006; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 10; Tumor length measurement: 20; Tumor width measurement: 18.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5.5; Tumor length measurement: 11; Tumor width measurement: 8.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 0.3.
   Pathology details: Consistent pathology review: Yes; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 80.6 years (29,444 days); Days to diagnosis: 172 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 172 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 172 days.
- Days to follow up: 191 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A23Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-DX-A23Y-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A23Y-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A23Y-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Disease multifocal indicator: Yes.
- Primary pathology, Tumor sizes, Tumor size 3: Lesion pathologic width: 8.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 191 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 191 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 172 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A23Y-01A-11D-A27O-01): tumor purity 0.55, ploidy 3.46, whole-genome doublings 1.
